Somatic mutation profile of tumor specimen TCGA-XF-A9SP-01A (aliquot TCGA-XF-A9SP-01A-11D-A391-08) from TCGA case TCGA-XF-A9SP, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 59.6 years (21,776 days).
Specimen TCGA-XF-A9SP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ed3a61b-409b-43d3-aca0-dc7229e52360.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A9SP-10A (Blood Derived Normal), aliquot TCGA-XF-A9SP-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad04140e-bc5f-4cde-af10-cea54d647041

The open-access MAF lists 336 somatic variants for this specimen: 238 protein-altering or splice-affecting, 92 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 199, Silent 92, Nonsense Mutation 23, Splice Site 7, Splice Region 5, Frame Shift Del 3, 3'Flank 2, 5'Flank 2, RNA 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADM | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs200724875, CM001046, CM060002; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- IDUA | c.1898C>T p.S633L | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs886043347, CM013757, CM150005, COSV56102323; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABHD13 | c.864G>C p.K288N | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65534632, COSV65535322; called by muse, mutect2, varscan2
- ACBD3 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 4/93 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1558121720, COSV64730309; called by muse, mutect2
- ACOT11 | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as rs748574584, COSV59347296; called by muse, mutect2, varscan2
- ACSBG2 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs746663021, COSV53123765; called by muse, mutect2, varscan2
- ACTB | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.399); catalogued as COSV59317815; called by muse, mutect2, varscan2
- ADAM23 | c.1999C>T p.R667* | Nonsense Mutation (SNP) | VAF 7/108 reads (6%) | catalogued as COSV100006881; called by muse, mutect2
- ADGRB3 | c.1436T>C p.I479T | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV65390449; called by muse, mutect2
- ADGRL3 | c.3247C>T p.R1083* (on ENST00000506720 / NM_001322402.2; = p.R1015* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 24/114 reads (21%) | catalogued as rs1036464370, COSV72230649; called by muse, mutect2, varscan2
- ADGRL3 | c.3677C>G p.S1226C (on ENST00000506720 / NM_001322402.2; = p.S1158C on NM_015236.6) | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV101546797, COSV72230116; called by muse, mutect2, varscan2
- AKAP13 | c.4778G>A p.R1593K | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.81); PolyPhen benign (0.022); catalogued as COSV63452840; called by muse, mutect2, varscan2
- ALAS1 | c.1413C>A p.F471L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59627395, COSV59628469; called by muse, mutect2, varscan2
- AMACR | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1333701891, COSV59460377; called by muse, mutect2, varscan2
- ANK1 | c.4232C>T p.S1411L | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as rs1302322996, COSV55877937; called by muse, mutect2, varscan2
- AP2B1 | c.670G>C p.D224H | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV51998215; called by muse, mutect2, varscan2
- AQP4 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV67218401; called by muse, mutect2, varscan2
- AREL1 | c.1016C>G p.S339C | Missense Mutation (SNP) | VAF 61/222 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.338); catalogued as COSV62665974; called by muse, mutect2, varscan2
- ARFGEF2 | c.4186G>A p.E1396K | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV64211514; called by muse, mutect2, varscan2
- ARMCX6 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62680633; called by muse, mutect2, varscan2
- ASPM | c.5252A>G p.Q1751R | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT tolerated (0.86); PolyPhen benign (0.186); catalogued as rs752671920, COSV54127655; called by muse, mutect2, varscan2
- ATP8B4 | c.1920G>C p.L640F | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as COSV99464066; called by muse, mutect2
- AZI2 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.391); catalogued as rs1422025494, COSV55423584; called by muse, mutect2, varscan2
- BABAM1 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53102812; called by muse, mutect2, varscan2
- BARD1 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV99638043; called by muse, mutect2
- BIRC6 | c.11219C>T p.S3740L | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.022); catalogued as COSV70197471; called by muse, mutect2, varscan2
- BMS1 | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65733478; called by muse, mutect2, varscan2
- BTN2A2 | c.952+1G>A p.X318_splice | Splice Site (SNP) | VAF 24/138 reads (17%) | catalogued as rs200463511, COSV61856950, COSV61857844; called by muse, mutect2
- C12orf66 | c.637C>G p.L213V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV61322824; called by muse, mutect2, varscan2
- C1QTNF3 | c.502A>G p.S168G | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV51468140; called by muse, mutect2, varscan2
- C6orf58 | c.403C>A p.L135M | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100314718; called by muse, mutect2
- CA6 | c.409-1G>A p.X137_splice | Splice Site (SNP) | VAF 26/188 reads (14%) | catalogued as COSV66261902; called by muse, mutect2, varscan2
- CARD14 | c.1942G>A p.G648S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748993106, COSV60122677; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CC2D2A | c.1752G>C p.W584C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as rs1467320427, COSV67502967; called by muse, mutect2
- CCDC151 | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.022); catalogued as COSV52950882; called by muse, mutect2
- CCSAP | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52909039, COSV99497286; called by muse, mutect2
- CD163L1 | c.3157C>T p.H1053Y | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV58013913; called by muse, mutect2, varscan2
- CD1D | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs750887347, COSV63808719; called by muse, mutect2, varscan2
- CDH10 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 36/101 reads (36%) | catalogued as rs1223214295, COSV100050312; called by muse, mutect2, varscan2
- CDH11 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs144201451, COSV51756993; called by muse, mutect2, varscan2
- CDH4 | c.2458G>A p.D820N | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1348662350, COSV64648564, COSV64674509; called by muse, mutect2, varscan2
- CFAP70 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs780152983, COSV100160235; called by muse, mutect2
- CFHR5 | c.686A>G p.H229R | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56820308; called by muse, mutect2, varscan2
- CHRNB3 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs768410524, COSV51494168; called by muse, mutect2, varscan2
- CINP | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV53736249, COSV99392235; called by muse, mutect2, varscan2
- CLMN | c.241-1G>T p.X81_splice | Splice Site (SNP) | VAF 6/48 reads (13%) | catalogued as COSV54180860; called by muse, mutect2
- CNTN6 | c.1045T>A p.Y349N | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1353519636, COSV63167641; called by muse, mutect2, varscan2
- CNTNAP3 | c.3265G>A p.D1089N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV99904126; called by muse, mutect2
- COBLL1 | c.623A>C p.Q208P (on ENST00000392717; = p.Q170P on NM_014900.5) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV52065560; called by muse, mutect2, varscan2
- COL2A1 | c.4204G>A p.E1402K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as rs759583931, COSV61528864; called by muse, mutect2, varscan2
- COL3A1 | c.2981C>A p.P994H | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58585142; called by muse, mutect2, varscan2
- CREB3 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as rs376855806, COSV59206028; called by muse, mutect2, varscan2
- CSRNP3 | c.623C>G p.S208* | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | catalogued as COSV100085222; called by muse, mutect2, varscan2
- CUX1 | c.709G>C p.E237Q (on ENST00000292535 / NM_181552.4; = p.E248Q on NM_001913.5) | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as rs1554506048, COSV52893709, COSV52895390; called by muse, mutect2
- CUX2 | c.3117G>C p.E1039D | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.358); catalogued as rs776601066, COSV55628440; called by muse, mutect2, varscan2
- CYP2A13 | c.1199G>C p.R400T | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV57836183, COSV57837005; called by muse, mutect2
- CYP4F22 | c.1278C>G p.I426M | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.291); catalogued as COSV54107598; called by muse, mutect2, varscan2
- DAND5 | c.324+1G>A p.X108_splice | Splice Site (SNP) | VAF 7/38 reads (18%) | catalogued as rs769094412, COSV57684014; called by muse, mutect2, varscan2
- DAXX | c.482C>G p.P161R | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.582); catalogued as COSV56468027; called by muse, mutect2, varscan2
- DCTN2 | c.632C>T p.S211F (on ENST00000548249 / NM_001261413.2; = p.S216F on NM_006400.4) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.139); catalogued as COSV63073788; called by muse, mutect2, varscan2
- DCTN4 | c.888C>G p.F296L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV69781979; called by muse, mutect2, varscan2
- DEPDC5 | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 96/177 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56694502; called by muse, mutect2, varscan2
- DLG3 | c.1481G>A p.G494E (on ENST00000374360 / NM_021120.4; = p.G157E on NM_020730.3) | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52081175; called by muse, mutect2, varscan2
- DMTF1 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV58684283; called by muse, mutect2, varscan2
- DNAH7 | c.4600G>T p.D1534Y | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56758388; called by muse, mutect2, varscan2
- DNAJC1 | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 14/221 reads (6%) | catalogued as COSV100977992; called by muse, mutect2
- DOCK11 | c.2949G>A p.K983= | Splice Region (SNP) | VAF 8/20 reads (40%) | catalogued as COSV52236287; called by mutect2, varscan2
- DPYD | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64594337; called by muse, mutect2
- DSC1 | c.1563T>G p.N521K | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV99937286; called by muse, mutect2
- DYSF | c.3277C>T p.R1093C | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs372817333; ClinVar: uncertain significance; called by muse, mutect2
- ECHDC1 | c.760C>T p.Q254* (on ENST00000531967 / NM_001139510.1; = p.Q248* on NM_001002030.2) | Nonsense Mutation (SNP) | VAF 16/105 reads (15%) | catalogued as COSV100541595; called by muse, mutect2, varscan2
- EHBP1 | c.2259C>G p.I753M | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.176); catalogued as rs1270038390, COSV50418033; called by muse, mutect2, varscan2
- EPHB3 | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.171); catalogued as rs752170254, COSV57805172; called by muse, mutect2, varscan2
- EQTN | c.457G>T p.D153Y | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV66218052; called by muse, mutect2
- EVPL | c.5276C>G p.S1759C | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV56909138; called by muse, mutect2
- EXPH5 | c.4593G>C p.E1531D | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV56200536; called by mutect2, varscan2
- FAM118B | c.414G>A p.M138I | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.838); catalogued as COSV100796837; called by muse, mutect2
- FANCI | c.2996C>T p.S999F (on ENST00000310775 / NM_001376911.1; = p.S939F on NM_018193.3) | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV55525221; called by muse, mutect2, varscan2
- FBLN1 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.439); catalogued as rs772492888, COSV53045495; called by muse, mutect2, varscan2
- FBLN7 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs369700908; called by muse, mutect2, varscan2
- FSIP2 | c.20617G>T p.G6873* | Nonsense Mutation (SNP) | VAF 10/64 reads (16%) | catalogued as rs373869471, COSV100554224; called by muse, mutect2, varscan2
- FUCA2 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as COSV50019924; called by muse, mutect2
- FUT2 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.836); catalogued as rs777828783, COSV67179110, COSV67179631; called by muse, mutect2, varscan2
- FZD6 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (1); PolyPhen possibly damaging (0.777); catalogued as COSV62471036; called by muse, mutect2, varscan2
- GART | c.1039G>C p.D347H | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.302); catalogued as COSV63113664; called by muse, mutect2, varscan2
- GATA2 | c.625G>C p.D209H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV62003754; called by muse, mutect2, varscan2
- GSDME | c.1164C>G p.F388L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.047); catalogued as COSV61651333, COSV61651996; called by muse, mutect2, varscan2
- GZMB | c.710T>A p.V237E | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV53540837; called by muse, mutect2, varscan2
- H2AJ | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63761974; called by muse, mutect2, varscan2
- HEATR5B | c.5210C>G p.S1737C | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV51851131; called by muse, mutect2, varscan2
- HELZ | c.2175C>G p.L725= | Splice Region (SNP) | VAF 21/93 reads (23%) | catalogued as COSV62377400; called by muse, mutect2, varscan2
- HIF3A | c.94G>A p.E32K (on ENST00000377670 / NM_152795.4; = p.P11= on NM_022462.4) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99355571; called by muse, mutect2, varscan2
- HMCN1 | c.6522T>A p.C2174* | Nonsense Mutation (SNP) | VAF 16/97 reads (16%) | catalogued as COSV99624981; called by muse, mutect2, varscan2
- HOXD10 | c.972G>T p.M324I | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV50891087; called by muse, mutect2, varscan2
- ICAM5 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs11669397, COSV53424283; called by muse, mutect2, varscan2
- IFRD1 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 3/49 reads (6%) | catalogued as COSV50045107, COSV99133656; called by muse, mutect2
- IL15 | c.26G>A p.R9K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.243); catalogued as COSV56724867; called by muse, mutect2, varscan2
- IL6R | c.744C>G p.F248L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV59815967; called by muse, mutect2
- IQGAP2 | c.3979G>C p.A1327P | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV57171343, COSV99167676; called by muse, mutect2, varscan2
- ITGA7 | c.1368C>A p.F456L (on ENST00000555728; = p.F412L on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as COSV57693562; called by muse, mutect2, varscan2
- ITGA7 | c.1243C>G p.L415V (on ENST00000555728; = p.L371V on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs777475535, COSV57693585; called by muse, mutect2, varscan2
- ITGAL | c.3256G>A p.E1086K | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs770821011, COSV63321222; called by muse, mutect2, varscan2
- ITPK1 | c.772A>C p.S258R | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.684); catalogued as COSV50894469; called by muse, mutect2
- ITPR1 | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs778868123, COSV56975810; called by muse, mutect2, varscan2
- IZUMO1 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV55803619; called by muse, mutect2, varscan2
- KALRN | c.5950G>C p.D1984H (on ENST00000360013 / NM_001024660.4; = p.D287H on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52253962; called by muse, mutect2, varscan2
- KCNK4 | c.312C>T p.I104= | Splice Region (SNP) | VAF 9/41 reads (22%) | catalogued as rs199677022, COSV60453768; called by muse, mutect2, varscan2
- KDM3A | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 24/105 reads (23%) | catalogued as COSV100460057; called by muse, mutect2, varscan2
- KDM7A | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.165); catalogued as COSV50090657; called by muse, mutect2, varscan2
- KDM7A | c.496G>C p.D166H | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV50090668; called by muse, mutect2, varscan2
- KIAA2026 | c.2561G>C p.R854T | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV101199141, COSV67354212; called by muse, mutect2, varscan2
- KMT5B | c.2321C>G p.S774C | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV58565293; called by muse, mutect2, varscan2
- KMT5B | c.1655C>G p.S552C | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs1307058162, COSV58564431; called by muse, mutect2, varscan2
- L2HGDH | c.169G>T p.G57* | Nonsense Mutation (SNP) | VAF 18/63 reads (29%) | catalogued as CM053940, COSV99910090; called by muse, mutect2, varscan2
- LCMT2 | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59789993; called by muse, mutect2, varscan2
- LGR6 | c.1714G>A p.V572M (on ENST00000367278 / NM_001017403.1; = p.V520M on NM_021636.3) | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.514); catalogued as rs763743707, COSV55154505; called by muse, mutect2, varscan2
- LNX2 | c.1808T>A p.L603* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100310513; called by muse, mutect2, varscan2
- LRRC41 | c.400del p.S134Pfs*116 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | catalogued as rs1557715031, COSV58440688; called by pindel, varscan2
- MAP1B | c.1577C>A p.P526H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV57096744; called by muse, mutect2, varscan2
- MAP3K20 | c.1808C>G p.S603* | Nonsense Mutation (SNP) | VAF 56/73 reads (77%) | catalogued as COSV100919408; called by muse, mutect2, varscan2
- MAPK10 | c.1030G>A p.E344K (on ENST00000359221 / NM_001351625.2; = p.E382K on NM_002753.5) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.222); catalogued as COSV60379358; called by muse, mutect2, varscan2
- MB | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); catalogued as COSV63094080; called by muse, mutect2, varscan2
- MCCC1 | c.947T>C p.V316A | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV55607695; called by muse, mutect2, varscan2
- MDK | c.150G>C p.K50N | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV100551129; called by muse, mutect2, varscan2
- ME1 | c.1531C>G p.L511V | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as COSV63838495; called by muse, mutect2, varscan2
- MEF2A | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV57530566, COSV57531640; called by muse, mutect2, varscan2
- MFSD5 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV61565313, COSV61565376; called by muse, mutect2, varscan2
- MMP19 | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs372055008, COSV59450945; called by muse, mutect2, varscan2
- MMUT | c.1579C>G p.Q527E | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51272920; called by muse, mutect2, varscan2
- MYOM3 | c.3097C>G p.P1033A | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV100141565; called by muse, mutect2
- N4BP2L2 | c.1455G>A p.M485I | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57227933; called by muse, mutect2
- NEIL1 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as COSV61833248; called by muse, mutect2, varscan2
- NEK1 | c.1619G>T p.R540L | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71454408, COSV71455264; called by muse, mutect2, varscan2
- NETO1 | c.1542-2A>T p.X514_splice | Splice Site (SNP) | VAF 11/90 reads (12%) | catalogued as COSV55004346; called by muse, mutect2, varscan2
- NFATC1 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.448); catalogued as rs1351294201, COSV53697770; called by muse, mutect2, varscan2
- NIM1K | c.1153G>T p.G385W | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58140589; called by muse, mutect2, varscan2
- NLRP11 | c.1445G>T p.R482I | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100789807, COSV64086535; called by muse, mutect2, varscan2
- NOP10 | c.80C>G p.T27S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV60995239; called by muse, mutect2, varscan2
- NUP153 | c.3008C>A p.S1003Y | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV50447606; called by muse, mutect2, varscan2
- NUTM1 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753733106, COSV61545966; called by muse, mutect2, varscan2
- ODC1 | c.830G>C p.R277T | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52171956, COSV99301372; called by muse, mutect2
- OR56A1 | c.933G>C p.Q311H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV57362214; called by muse, mutect2, varscan2
- OR5L2 | c.276C>G p.I92M | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV65723714, COSV65724959; called by muse, mutect2, varscan2
- OR6C1 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as COSV65573067, COSV65573189; called by muse, mutect2, varscan2
- OR8K5 | c.839T>C p.L280S | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1422909178, COSV57888386; called by muse, mutect2, varscan2
- OXGR1 | c.754G>A p.V252I | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as rs144457939, COSV53658362; called by muse, mutect2, varscan2
- PALB2 | c.2140G>A p.D714N | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as rs45537237, COSV55163965; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PAXBP1 | c.2150G>A p.G717E | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0.428); catalogued as COSV51607950; called by muse, mutect2, varscan2
- PCDH15 | c.5108C>T p.S1703L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV57276335; called by muse, mutect2, varscan2
- PCNX4 | c.293C>G p.S98* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100469979; called by muse, mutect2, varscan2
- PDS5B | c.2452G>C p.V818L | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.43); catalogued as COSV59725479; called by muse, mutect2, varscan2
- PGLYRP1 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV50516644; called by muse, mutect2, varscan2
- PHF20L1 | c.1218C>G p.F406L | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV55190592; called by muse, mutect2, varscan2
- PIP4K2A | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0.127); catalogued as rs371987267; called by muse, mutect2, varscan2
- PLXNB1 | c.5680G>A p.E1894K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99602374; called by muse, mutect2
- POLA2 | c.123G>A p.M41I | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV55481789; called by muse, mutect2, varscan2
- PPP3CB | c.1154A>T p.E385V | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV61151496; called by muse, mutect2, varscan2
- PRICKLE2 | c.2233C>T p.R745C (on ENST00000295902; = p.R689C on NM_198859.4) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757119488, COSV55764918, COSV55767259; called by muse, mutect2, varscan2
- PRLR | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV51494486, COSV51495899; called by muse, mutect2, varscan2
- PRX | c.2228C>A p.P743H | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.912); catalogued as COSV52528856; called by muse, mutect2, varscan2
- PSMA6 | c.734G>C p.R245T | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV54836897, COSV54838036; called by muse, mutect2, varscan2
- PTCHD3 | c.1766G>A p.R589K | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.925); catalogued as COSV71256568; called by muse, mutect2
- PTCHD3 | c.1631G>C p.R544T | Missense Mutation (SNP) | VAF 85/172 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71256570, COSV71257185; called by muse, mutect2, varscan2
- PTPRK | c.4131-1G>C p.X1377_splice (on ENST00000368215 / NM_001291984.2; = p.X1378_splice on NM_002844.4) | Splice Site (SNP) | VAF 26/72 reads (36%) | catalogued as COSV63894544; called by muse, mutect2, varscan2
- PYM1 | c.159C>G p.F53L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.129); catalogued as COSV56811755; called by muse, mutect2, varscan2
- R3HDM1 | c.544A>G p.I182V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV51522827; called by muse, mutect2, varscan2
- RAB34 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 15/56 reads (27%) | catalogued as rs762657234, COSV99973896; called by muse, mutect2, varscan2
- RAD50 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV54749702, COSV54758597; called by muse, mutect2, varscan2
- RANBP2 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51701660, COSV99311378; called by muse, mutect2, varscan2
- RBM5 | c.1024C>T p.Q342* | Nonsense Mutation (SNP) | VAF 9/61 reads (15%) | catalogued as rs1375558137, COSV100762173; called by muse, mutect2, varscan2
- RBM5 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV61737060; called by muse, varscan2
- RBM5 | c.1190C>G p.S397* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as COSV100762174; called by muse, varscan2
- RBP2 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV51673341; called by muse, mutect2
- REV3L | c.8270G>A p.R2757K | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV62617378; called by muse, mutect2, varscan2
- RGS19 | c.79G>T p.D27Y | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as COSV58657473; called by muse, mutect2, varscan2
- RNASEH1 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV59438398; called by muse, mutect2, varscan2
- RNF10 | c.935G>A p.W312* | Nonsense Mutation (SNP) | VAF 31/111 reads (28%) | catalogued as COSV100378488; called by muse, mutect2, varscan2
- ROR2 | c.2620G>A p.V874I | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs200867550, COSV65217935; ClinVar: benign; called by muse, mutect2, varscan2
- RPS7 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as COSV59232711; called by muse, mutect2, varscan2
- RTN3 | c.1985G>A p.R662K (on ENST00000377819 / NM_001265589.2; = p.R643K on NM_201428.3) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as COSV58027949; called by muse, mutect2, varscan2
- SACS | c.3082C>G p.P1028A | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs376187491, COSV66547458; called by muse, mutect2, varscan2
- SCN5A | c.3809C>T p.A1270V (on ENST00000333535 / NM_198056.3; = p.A1269V on NM_000335.5) | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.672); catalogued as COSV61120427; called by muse, mutect2
- SHKBP1 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52538814; called by muse, mutect2
- SHPRH | c.4478C>T p.S1493L (on ENST00000275233 / NM_001042683.3; = p.S1497L on NM_173082.3) | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as rs1466868994, COSV51606905; called by muse, mutect2, varscan2
- SKIDA1 | c.2145G>C p.K715N | Missense Mutation (SNP) | VAF 19/418 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1203905821, COSV101481368, COSV71610812; called by muse, mutect2
- SLC10A4 | c.588C>A p.L196= | Splice Region (SNP) | VAF 5/57 reads (9%) | catalogued as COSV56718395, COSV56719982; called by muse, mutect2, varscan2
- SLC14A2 | c.2078G>A p.W693* | Nonsense Mutation (SNP) | VAF 10/87 reads (11%) | catalogued as COSV54905699, COSV99675131; called by muse, mutect2, varscan2
- SLC26A3 | c.2063-1G>C p.X688_splice | Splice Site (SNP) | VAF 6/42 reads (14%) | catalogued as CS126103, COSV60639633; called by muse, mutect2, varscan2
- SLC5A9 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs756014240, COSV52582778; called by muse, mutect2, varscan2
- SLC6A8 | c.886G>C p.D296H | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99465759; called by muse, mutect2
- SLIT1 | c.2048G>T p.G683V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs764022023, COSV56586418; called by muse, mutect2, varscan2
- SLITRK4 | c.2130G>C p.M710I | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV62022944; called by muse, mutect2, varscan2
- SLK | c.2953G>T p.E985* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as COSV100211535, COSV99046687; called by muse, mutect2, varscan2
- SLX4IP | c.400G>C p.D134H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.35); catalogued as COSV57945550; called by muse, mutect2, varscan2
- SMTNL1 | c.1071A>T p.K357N (on ENST00000399154; = p.K394N on NM_001105565.2) | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT tolerated (0.99); PolyPhen benign (0.006); catalogued as COSV67699095; called by muse, mutect2
- SPAG17 | c.3514G>C p.V1172L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.095); catalogued as rs536383245, COSV60456065; called by muse, mutect2
- SPATA20 | c.677G>A p.R226Q (on ENST00000356488 / NM_001258372.1; = p.R242Q on NM_022827.4) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.031); catalogued as rs780703307, COSV50066239; called by muse, mutect2, varscan2
- SPEN | c.6289G>C p.D2097H | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV65359972; called by muse, mutect2, varscan2
- SPOPL | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV54512499, COSV54512829; called by muse, mutect2, varscan2
- SPRY2 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as rs200813001, COSV65701321; called by muse, mutect2, varscan2
- SRGAP1 | c.3134G>C p.R1045T | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.529); catalogued as COSV61896230; called by muse, mutect2, varscan2
- STAT4 | c.237G>C p.L79F | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.776); catalogued as rs1405872272, COSV100635977; called by muse, mutect2
- STK31 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.837); catalogued as COSV100669334, COSV63455136; called by muse, mutect2, varscan2
- SUZ12 | c.1748G>T p.S583I | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100496735; called by muse, mutect2
- SYBU | c.578G>A p.G193D (on ENST00000276646 / NM_001099754.2; = p.G192D on NM_017786.6) | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as COSV52616085; called by muse, mutect2
- TAF1L | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.835); catalogued as rs750863247, COSV54260125; called by muse, mutect2, varscan2
- TAOK1 | c.2518C>T p.L840F | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.548); catalogued as rs1208025308, COSV55590169, COSV99914528; called by muse, mutect2
- TESPA1 | c.463G>A p.D155N (on ENST00000316577 / NM_001098815.3; = p.D17N on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.937); catalogued as COSV57258113; called by muse, mutect2
- TMEM132E | c.2080C>T p.R694C (on ENST00000321639; = p.R784C on NM_001304438.2) | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1318148313, COSV58695915; called by muse, mutect2, varscan2
- TMEM200C | c.434C>A p.S145Y | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV101274794; called by muse, mutect2, varscan2
- TMEM94 | c.3191C>T p.S1064F | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1230034811, COSV58594490; called by muse, mutect2, varscan2
- TMPRSS4 | c.156C>T p.L52= | Splice Region (SNP) | VAF 14/50 reads (28%) | catalogued as COSV71108717; called by muse, mutect2, varscan2
- TNNI3K | c.2467C>G p.H823D | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV58550567, COSV58558920; called by muse, mutect2, varscan2
- TOLLIP | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757526937, COSV55135825; called by muse, mutect2, varscan2
- TOM1L2 | c.1181C>G p.S394C (on ENST00000379504 / NM_001350333.2; = p.S344C on NM_001033551.3) | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV58885070; called by muse, mutect2, varscan2
- TPCN1 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as COSV59234012; called by muse, varscan2
- TTN | c.19526C>G p.S6509* (on ENST00000591111; = p.S5582* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as rs775578377, COSV100597541; called by muse, mutect2, varscan2
- TXNDC2 | c.1286C>G p.S429C (on ENST00000306084 / NM_001098529.2; = p.S362C on NM_032243.6) | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as COSV60152708; called by muse, mutect2, varscan2
- UBR4 | c.1465C>G p.Q489E | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64385874; called by muse, mutect2, varscan2
- UGT1A6 | c.325C>G p.Q109E | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.14); catalogued as COSV59385816; called by muse, mutect2, varscan2
- VAT1L | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.977); catalogued as COSV56817288; called by muse, mutect2, varscan2
- VPS54 | c.1769C>G p.S590* | Nonsense Mutation (SNP) | VAF 11/149 reads (7%) | catalogued as COSV99707808; called by muse, mutect2
- VWA3B | c.2155C>G p.Q719E | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV68241994; called by muse, mutect2, varscan2
- WASF2 | c.1363G>T p.E455* | Nonsense Mutation (SNP) | VAF 9/54 reads (17%) | catalogued as COSV101420727; called by muse, mutect2, varscan2
- WNK4 | c.2566C>T p.P856S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV55902909; called by muse, mutect2, varscan2
- XAF1 | c.453C>G p.I151M | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV60971614; called by muse, mutect2, varscan2
- XIRP2 | c.5083G>A p.A1695T (on ENST00000628543; = p.A1870T on NM_152381.6) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV54691647; called by muse, mutect2, varscan2
- ZNF208 | c.536T>C p.V179A | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.434); catalogued as rs780498478, COSV68103152; called by mutect2, varscan2
- ZNF470 | c.1114G>C p.D372H | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV57968345; called by muse, mutect2, varscan2
- ZNF572 | c.1154G>C p.R385T | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100073993, COSV60001542; called by muse, mutect2
- ZNF574 | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV55902546, COSV55904527; called by muse, mutect2, varscan2
- ZNF599 | c.1494G>C p.M498I | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.675); catalogued as COSV61395842; called by muse, mutect2, varscan2
- ZNF93 | c.41C>G p.S14C | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as COSV104416049, COSV59374903; called by muse, mutect2, varscan2
- ARID1A | c.6420del p.F2141Sfs*59 | Frame Shift Del (DEL) | VAF 11/83 reads (13%) | called by mutect2, pindel, varscan2
- PCDHGA2 | c.773del p.G258Afs*7 | Frame Shift Del (DEL) | VAF 11/105 reads (10%) | called by mutect2, pindel, varscan2
- SMTNL1 | c.1073A>C p.Y358S (on ENST00000399154; = p.Y395S on NM_001105565.2) | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- STAT5A | c.1083_1094del p.V362_N365del | In Frame Del (DEL) | VAF 10/78 reads (13%) | called by mutect2, pindel
- VN1R5 | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.993); called by muse, mutect2
- ACAN | c.6387G>C p.L2129= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV61358543; called by muse, mutect2, varscan2
- ACSM3 | c.1755A>T p.T585= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV55500718; called by muse, mutect2, varscan2
- ADARB2 | c.2136G>A p.Q712= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs1314058470, COSV67182010; called by muse, mutect2, varscan2
- AGL | c.4146C>T p.T1382= | Silent (SNP) | VAF 11/115 reads (10%) | catalogued as rs767272437, COSV54050752; ClinVar: likely benign; called by muse, mutect2, varscan2
- AMER2 | c.1509G>A p.K503= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as COSV63436870; called by muse, mutect2, varscan2
- ANKRD11 | c.2274G>A p.L758= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV56358484, COSV56359427; called by muse, mutect2, varscan2
- ANKRD55 | c.1746G>A p.R582= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV61945910; called by muse, mutect2, varscan2
- APOB | c.4558C>T p.L1520= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV51930322; called by muse, mutect2, varscan2
- ARRDC5 | c.753G>C p.L251= (on ENST00000381781; = p.L237= on NM_001080523.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs370329197, COSV67787857; called by muse, mutect2, varscan2
- C1orf35 | c.642C>T p.A214= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs778053863, COSV55254479; called by muse, mutect2, varscan2
- CC2D1A | c.2733G>A p.R911= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV54308322; called by muse, mutect2, varscan2
- CD109 | c.801A>T p.T267= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV54647718; called by muse, mutect2, varscan2
- CD1B | c.822G>A p.A274= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as rs367979289; called by muse, mutect2, varscan2
- CD209 | c.1003C>T p.L335= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV99213697; called by muse, mutect2
- CD93 | c.768C>A p.L256= | Silent (SNP) | VAF 16/115 reads (14%) | catalogued as COSV55664019, COSV55664339; called by muse, mutect2, varscan2
- CD93 | c.430C>T p.L144= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV55664629, COSV99848950; called by muse, mutect2
- CDC42BPB | c.3636C>G p.L1212= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs760589634, COSV63474546; called by muse, mutect2, varscan2
- CDCP1 | c.501C>A p.I167= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs780582029, COSV56104559, COSV56104646; called by muse, mutect2, varscan2
- CEP192 | c.5916C>A p.I1972= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV58062147; called by muse, mutect2, varscan2
- CES2 | c.1554G>A p.L518= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV57696554; called by muse, mutect2, varscan2
- CLMP | c.741G>C p.L247= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV71649529; called by muse, mutect2, varscan2
- COL5A3 | c.2064G>A p.E688= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs747769168, COSV53408737; called by muse, mutect2, varscan2
- CRB1 | c.1599G>C p.V533= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV66329306; called by muse, mutect2, varscan2
- DAXX | c.966C>T p.I322= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV56468016; called by muse, mutect2, varscan2
- DHPS | c.147C>T p.F49= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV52951591, COSV52951708, COSV52952106; called by muse, mutect2, varscan2
- DSC1 | c.214C>T p.L72= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as rs1480752806, COSV99937287; called by muse, mutect2
- EDN3 | c.198G>A p.V66= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV61107388; called by muse, mutect2, varscan2
- EPAS1 | c.666C>T p.L222= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs756347726, COSV55385453; called by muse, mutect2, varscan2
- EPHA5 | c.2439G>A p.V813= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV56638639; called by muse, mutect2, varscan2
- EVPL | c.4938C>T p.L1646= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV56909154; called by muse, mutect2, varscan2
- FBXO42 | c.1218C>T p.G406= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as rs1377911465, COSV100981664; called by muse, mutect2
- FCRL6 | c.1140G>A p.R380= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV58940371; called by muse, mutect2, varscan2
- FMNL1 | c.288C>T p.V96= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV58956144; called by muse, mutect2, varscan2
- GALNT12 | c.1434C>G p.L478= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV66662452; called by muse, mutect2, varscan2
- GRM5 | c.537G>C p.L179= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV59599049; called by muse, mutect2, varscan2
- H2BC18 | c.222C>T p.I74= | Silent (SNP) | VAF 38/121 reads (31%) | catalogued as rs782575950, COSV100516145, COSV58944587; called by muse, mutect2, varscan2
- H2BC6 | c.222C>T p.I74= | Silent (SNP) | VAF 19/123 reads (15%) | catalogued as rs769608700, COSV61590933; called by muse, mutect2, varscan2
- HIBADH | c.843C>G p.L281= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV55312879, COSV55315786; called by muse, mutect2, varscan2
- IGSF9 | c.1788C>T p.S596= (on ENST00000368094 / NM_001135050.2; = p.S580= on NM_020789.4) | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs1176219207, COSV63639421; called by muse, mutect2, varscan2
- IL20RB | c.783C>G p.L261= | Silent (SNP) | VAF 30/251 reads (12%) | catalogued as COSV59047282; called by muse, mutect2, varscan2
- IRF2 | c.477G>C p.A159= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as COSV66929020, COSV66929086; called by muse, mutect2, varscan2
- ITPK1 | c.771G>T p.P257= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV50894496; called by mutect2, varscan2
- ITPKA | c.1023C>A p.S341= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV53027159, COSV99541181; called by muse, mutect2, varscan2
- KCNV1 | c.1050C>T p.L350= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV52085396, COSV99819129; called by muse, mutect2, varscan2
- KIF1B | c.4912C>T p.L1638= (on ENST00000377086 / NM_001365952.1; = p.L1592= on NM_015074.3) | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV99823124; called by muse, mutect2
- KIF9 | c.882G>A p.Q294= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV55518626; called by muse, mutect2, varscan2
- LRP1B | c.6384C>G p.V2128= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV67202442; called by muse, mutect2, varscan2
- LTBP3 | c.3087G>A p.G1029= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV54211521; called by mutect2, varscan2
- MEGF8 | c.564G>A p.L188= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs1371248862, COSV99234717; called by muse, mutect2
- MPP2 | c.801C>T p.L267= (on ENST00000461854 / NM_001278372.2; = p.L243= on NM_005374.5) | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs146551557; called by muse, mutect2, varscan2
- MTHFD1 | c.171G>T p.L57= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV53699252; called by muse, mutect2, varscan2
- MYO10 | c.5496C>T p.A1832= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV57019487; called by muse, mutect2, varscan2
- MYRF | c.2307C>T p.I769= (on ENST00000278836 / NM_001127392.3; = p.I760= on NM_013279.4) | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV99606599; called by muse, mutect2, varscan2
- NDUFB9 | c.174G>A p.A58= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as rs1344199544, COSV52674643; called by muse, mutect2, varscan2
- NFATC2 | c.1299C>T p.V433= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV65354462; called by muse, mutect2, varscan2
- NKPD1 | c.2160C>G p.L720= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs1411839466; called by muse, mutect2
- NLRP10 | c.867C>T p.L289= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as COSV60779651; called by muse, mutect2, varscan2
- OR6K3 | c.249C>A p.S83= (on ENST00000368146; = p.S67= on NM_001005327.2) | Silent (SNP) | VAF 11/155 reads (7%) | catalogued as COSV63745503, COSV63746522; called by muse, mutect2
- P2RY4 | c.511C>T p.L171= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV65736869; called by muse, mutect2
- P2RY4 | c.357C>T p.L119= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100996987; called by muse, mutect2
- PARP1 | c.2997G>A p.L999= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV64689809; called by muse, mutect2, varscan2
- PCDHAC2 | c.1761G>A p.S587= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs782634339, COSV53838691; called by muse, mutect2, varscan2
- PCDHB6 | c.1791C>T p.N597= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as rs782378880, COSV99169947; called by muse, mutect2, varscan2
- PDE1B | c.1281C>T p.F427= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV54491315; called by muse, mutect2, varscan2
- PHTF2 | c.1857C>T p.L619= (on ENST00000248550 / NM_001366089.1; = p.L581= on NM_020432.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as COSV50324777; called by muse, mutect2, varscan2
- PKHD1 | c.4495C>T p.L1499= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as COSV61868235; called by muse, mutect2, varscan2
- PLCD1 | c.2058G>C p.T686= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV52183454; called by muse, mutect2, varscan2
- POLR3GL | c.465G>A p.E155= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV65215300; called by muse, mutect2, varscan2
- PRKAG3 | c.891C>T p.V297= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV52101360; called by muse, varscan2
- REC8 | c.1131C>G p.L377= | Silent (SNP) | VAF 65/233 reads (28%) | catalogued as COSV61015824; called by muse, mutect2, varscan2
- SHKBP1 | c.2028C>T p.D676= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV99180601; called by muse, mutect2, varscan2
- SHOX2 | c.837A>C p.A279= (on ENST00000441443 / NM_006884.3; = p.A303= on NM_003030.4) | Silent (SNP) | VAF 43/134 reads (32%) | catalogued as COSV67463708; called by muse, mutect2, varscan2
- SP100 | c.1623T>C p.S541= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV50976465; called by muse, mutect2, varscan2
- SPIDR | c.93C>T p.V31= | Silent (SNP) | VAF 29/179 reads (16%) | called by muse, mutect2, varscan2
- SULT1A2 | c.426C>T p.F142= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs1227871641, COSV57681292, COSV57682885; called by muse, mutect2, varscan2
- TCIM | c.156C>T p.F52= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV59927806; called by muse, varscan2
- TMED8 | c.351G>A p.Q117= | Silent (SNP) | VAF 31/130 reads (24%) | catalogued as COSV53625947; called by muse, mutect2, varscan2
- TMEM181 | c.1236C>T p.I412= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs187514314, COSV100892475, COSV65562685; called by muse, mutect2, varscan2
- TMPRSS9 | c.891C>T p.L297= (on ENST00000648592; = p.L263= on NM_182973.2) | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV60226696; called by muse, mutect2, varscan2
- TPTE | c.1114A>C p.R372= (on ENST00000618007 / NM_199261.4; = p.R354= on NM_199259.4) | Silent (SNP) | VAF 15/116 reads (13%) | called by muse, mutect2, varscan2
- TRIM9 | c.1962T>C p.N654= | Silent (SNP) | VAF 40/261 reads (15%) | catalogued as COSV53615317; called by muse, mutect2, varscan2
- TTC16 | c.1269G>A p.Q423= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV64778002; called by muse, mutect2, varscan2
- TTC26 | c.975C>T p.V325= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs1188006641, COSV58270591; called by muse, mutect2, varscan2
- TTF2 | c.2769C>G p.L923= | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as rs1209854371, COSV65632314; called by muse, mutect2, varscan2
- UQCRC2 | c.96G>A p.P32= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs201388758, COSV51671415; called by muse, mutect2, varscan2
- XIRP2 | c.96T>C p.H32= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV99739175; called by muse, mutect2
- XKR3 | c.129C>G p.L43= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV58885344; called by muse, mutect2, varscan2
- XYLT2 | c.1875G>A p.L625= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV50016617, COSV50017226; called by muse, mutect2, varscan2
- ZNF331 | c.102G>A p.V34= | Silent (SNP) | VAF 10/179 reads (6%) | catalogued as COSV53475962; called by muse, mutect2
- ZNF341 | c.192G>T p.S64= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV61007540, COSV61007957; called by muse, mutect2, varscan2
- ZNF426 | c.822C>T p.L274= | Silent (SNP) | VAF 18/159 reads (11%) | catalogued as COSV53468748; called by muse, mutect2, varscan2
- ZNF451 | c.2424C>T p.F808= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV62597213; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73821987 G>A | 5'Flank (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501145 ins T | 5'Flank (INS) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- PCYT1A | chr3:196230058 C>T | 3'Flank (SNP) | VAF 4/19 reads (21%) | catalogued as COSV53060231; called by mutect2, varscan2
- SLITRK2 | chrX:145827924 C>G | 3'Flank (SNP) | VAF 5/23 reads (22%) | catalogued as COSV59424268; called by muse, mutect2, varscan2
- SSPOP | n.3072del | RNA (DEL) | VAF 8/12 reads (67%) | called by mutect2, varscan2
- TMEM179 | c.522+9C>T | Intron (SNP) | VAF 18/33 reads (55%) | catalogued as rs1566742644, COSV58794934; called by muse, mutect2, varscan2
